Somatic mutation profile of tumor specimen TCGA-41-2572-01A (aliquot TCGA-41-2572-01A-01D-1353-08) from TCGA case TCGA-41-2572, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.1 years (24,505 days).
Specimen TCGA-41-2572-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dcd954e1-9cbc-409a-aec8-059a45a866bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-2572-10A (Blood Derived Normal), aliquot TCGA-41-2572-10A-01D-1353-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba3d4162-e515-4791-8370-ddadef99e1bf

The open-access MAF lists 53 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 82/189 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACP4 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs751444282, COSV54517011; called by muse, mutect2, varscan2
- ACSL1 | c.1739G>C p.S580T | Missense Mutation (SNP) | VAF 341/810 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV55662941; called by muse, mutect2, varscan2
- ADAM30 | c.1299G>T p.L433F | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.364); catalogued as COSV65561220; called by muse, mutect2, varscan2
- ADGRE5 | c.1393G>A p.A465T (on ENST00000242786 / NM_078481.4; = p.A372T on NM_001784.5) | Missense Mutation (SNP) | VAF 110/327 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs775651358, COSV54411092; called by muse, mutect2, varscan2
- AHR | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777712668, COSV54123680; called by muse, varscan2
- ANO4 | c.2804G>A p.R935H (on ENST00000392977 / NM_001286615.2; = p.R900H on NM_178826.4) | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs143188971; called by muse, mutect2, varscan2
- CCT8L2 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 162/420 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747115852, COSV100743275, COSV63462569; called by muse, mutect2, varscan2
- CD22 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs747460337, COSV50053857; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTSB | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs781379754, COSV61540743; called by muse, mutect2, varscan2
- DROSHA | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs928405820, COSV60776607; called by muse, mutect2, varscan2
- FAM32A | c.220A>G p.M74V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV54624531; called by muse, mutect2
- FAM83B | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753104783, COSV60922418; called by muse, mutect2, varscan2
- GLIS1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 53/147 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs758828860, COSV56549356; called by muse, mutect2, varscan2
- GPX1 | c.167A>C p.Y56S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.509); catalogued as COSV69042549; called by muse, mutect2, varscan2
- HS3ST1 | c.341A>G p.Q114R | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as rs974239157, COSV50023785; called by muse, mutect2, varscan2
- HSPBP1 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV55334302; called by muse, mutect2, varscan2
- HSPBP1 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs755189382, COSV55334309; called by muse, mutect2, varscan2
- HYDIN | c.10618G>A p.A3540T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs774036864, COSV66871097; called by muse, mutect2, varscan2
- HYDIN | c.10129C>T p.R3377C | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as rs779031423, COSV101151299, COSV101157939; called by muse, mutect2, varscan2
- IGKV4-1 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | catalogued as rs376415297; called by muse, mutect2, varscan2
- KEL | c.1963C>T p.R655W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs370938244, COSV62335275; called by muse, mutect2, varscan2
- KIR3DL3 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 120/369 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1324781250; called by muse, mutect2, varscan2
- MYH1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs780763560, COSV56843727, COSV56851492; called by muse, mutect2, varscan2
- OR13G1 | c.362T>G p.V121G | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62944312; called by muse, mutect2
- OR8S1 | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | PolyPhen possibly damaging (0.499); catalogued as rs767389591, COSV59599944; called by muse, mutect2, varscan2
- RYR3 | c.2560G>A p.V854I | Missense Mutation (SNP) | VAF 157/403 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.055); catalogued as rs777149669, COSV66791128; called by muse, mutect2, varscan2
- SCN10A | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs1294999278, COSV71861574; called by muse, mutect2, varscan2
- SCYL2 | c.1453A>C p.K485Q | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV62568983; called by muse, mutect2, varscan2
- SEMA4A | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV61772817; called by muse, mutect2, varscan2
- SERPINB7 | c.586A>G p.K196E | Missense Mutation (SNP) | VAF 122/286 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.13); catalogued as COSV60534080, COSV60534368; called by muse, mutect2, varscan2
- SLC30A5 | c.634C>G p.L212V | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV67449625; called by muse, mutect2, varscan2
- TET2 | c.802T>G p.S268A | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV54412929; called by muse, mutect2, varscan2
- TTN | c.98255C>T p.T32752I (on ENST00000591111; = p.T25328I on NM_003319.4) | Missense Mutation (SNP) | VAF 34/106 reads (32%) | PolyPhen possibly damaging (0.827); catalogued as rs372299779; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP22 | c.182G>A p.C61Y | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV54945469; called by muse, mutect2, varscan2
- XIRP2 | c.6718A>G p.K2240E (on ENST00000628543; = p.K2415E on NM_152381.6) | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV54703023; called by muse, mutect2, varscan2
- FGD4 | c.2041dup p.Q681Pfs*18 | Frame Shift Ins (INS) | VAF 55/190 reads (29%) | called by mutect2, pindel, varscan2
- TRAJ58 | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2, varscan2
- ATP6V0D1 | c.522C>T p.D174= | Silent (SNP) | VAF 108/272 reads (40%) | catalogued as rs1040061766, COSV52098134; called by muse, mutect2, varscan2
- FBLN2 | c.1917C>T p.D639= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs200610728, COSV55485106; called by muse, mutect2, varscan2
- GALNT13 | c.507C>T p.Y169= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs187976407; called by muse, mutect2, varscan2
- HLA-DPA1 | c.582C>T p.C194= | Silent (SNP) | VAF 170/484 reads (35%) | catalogued as COSV70089155; called by muse, mutect2, varscan2
- IL13RA2 | c.435C>T p.C145= | Silent (SNP) | VAF 52/71 reads (73%) | catalogued as rs199528071, COSV54565300; called by muse, mutect2, varscan2
- IL22RA1 | c.153G>A p.T51= | Silent (SNP) | VAF 26/88 reads (30%) | catalogued as rs780847323, COSV54628862; called by muse, mutect2, varscan2
- MSANTD1 | c.213C>T p.N71= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs143238822; called by muse, mutect2, varscan2
- MYBL2 | c.1320G>A p.T440= | Silent (SNP) | VAF 65/231 reads (28%) | catalogued as rs751255222, COSV53830055; called by muse, mutect2, varscan2
- OR2A7 | c.600C>T p.A200= | Silent (SNP) | VAF 14/115 reads (12%) | catalogued as rs745481161, COSV101512230; called by mutect2, varscan2
- P2RY2 | c.423C>T p.S141= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as COSV60775509; called by muse, mutect2, varscan2
- P2RY8 | c.783C>T p.I261= | Silent (SNP) | VAF 43/112 reads (38%) | catalogued as COSV101184058, COSV67176705, COSV67176831; called by muse, mutect2, varscan2
- PALM | c.843C>T p.G281= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs199542927, COSV52768364; called by mutect2, varscan2
- PCDHGA2 | c.1674C>T p.N558= | Silent (SNP) | VAF 180/394 reads (46%) | catalogued as rs150000282; called by muse, mutect2, varscan2
- PTPRC | c.837G>A p.A279= | Silent (SNP) | VAF 88/194 reads (45%) | catalogued as rs137909392; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZDHHC23 | chr3:113965275 C>T | 3'Flank (SNP) | VAF 97/295 reads (33%) | catalogued as COSV55672452; called by muse, mutect2, varscan2
